Gene-level copy-number profile of tumor specimen ALCH-AELW-TTP1-A from ALCHEMIST case ALCH-AELW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.4 years (22,424 days).
Specimen ALCH-AELW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0486d450-d403-4ae6-9952-b4d0c016c846.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AELW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/c93bcf6e-c595-4268-93ee-0f262c65aef7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 603; copy number 1: 12,868; copy number 2: 40,594; copy number 3: 3,078; copy number 4: 1,595; copy number 5: 155; copy number 7: 2; copy number 9: 2.

Homozygous deletions (total copy number 0; autosomes only): 99 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:944,203–959,309, 1 gene (within-gene range 0–2): NOC2L.
- chr1:9,588,911–9,614,877, 1 gene: TMEM201.
- chr1:20,719,731–20,732,837, 1 gene: SH2D5.
- chr1:22,563,489–22,603,595, 1 gene: EPHA8.
- chr1:151,806,071–151,840,557, 2 genes (within-gene range 0–2): RORC, C2CD4D.
- chr2:219,434,843–219,493,629, 1 gene (within-gene range 0–1): SPEG.
- chr3:48,599,002–48,669,174, 7 genes: UQCRC1, TMEM89, SLC26A6, MIR6824, CELSR3, MIR4793, LINC02585.
- chr3:126,973,065–127,037,392, 2 genes: AC011199.1, PLXNA1.
- chr3:128,479,427–128,502,970, 2 genes: GATA2, GATA2-AS1.
- chr4:836,512–837,224, 1 gene: AC139887.3.
- chr4:1,617,915–1,684,261, 2 genes (within-gene range 0–2): FAM53A, Y_RNA.
- chr4:1,793,293–1,808,872, 1 gene: FGFR3.
- chr4:7,460,028–7,460,118, 1 gene (within-gene range 0–1): MIR4274.
- chr5:175,796,310–175,884,021, 1 gene: CPLX2.
- chr6:32,005,636–32,041,644, 6 genes (within-gene range 0–2): CYP21A1P, TNXA, STK19B, C4B, C4B-AS1, CYP21A2.
- chr9:61,190,003–61,627,683, 9 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr9:93,951,627–93,959,140, 2 genes: BARX1, BARX1-DT.
- chr9:121,519,816–121,520,424, 1 gene: HMGB1P37.
- chr9:121,574,891–121,576,214, 1 gene (within-gene range 0–1): AL357936.1.
- chr10:117,542,445–117,549,546, 1 gene (within-gene range 0–2): EMX2.
- chr10:132,186,948–132,205,759, 1 gene: DPYSL4.
- chr11:369,499–382,117, 1 gene: B4GALNT4.
- chr15:25,189,414–25,245,559, 31 genes (within-gene range 0–2): SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41.
- chr16:1,308,880–1,329,777, 3 genes (within-gene range 0–2): UBE2I, AL031714.1, RPS20P2.
- chr16:1,512,979–1,514,675, 1 gene (within-gene range 0–2): AL031705.1.
- chr16:20,586,550–20,607,107, 1 gene (within-gene range 0–2): ACSM5P1.
- chr17:142,789–181,650, 1 gene (within-gene range 0–1): DOC2B.
- chr17:17,507,351–17,508,308, 1 gene (within-gene range 0–2): AC020558.2.
- chr17:44,115,912–44,162,476, 3 genes (within-gene range 0–2): AC023855.1, RNU6-131P, HROB.
- chr18:37,243,040–37,762,131, 6 genes (within-gene range 0–2): CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr19:22,520,995–22,533,494, 2 genes (within-gene range 0–2): AC011467.1, LINC01233.
- chr21:37,006,150–37,019,662, 1 gene: RIPPLY3.
- chr21:43,446,601–43,453,902, 1 gene: LINC00319.
- chr21:43,465,309–43,467,298, 1 gene (within-gene range 0–2): AP001048.1.
- chr22:24,181,487–24,189,106, 1 gene: SUSD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 159 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:23,951,348–24,178,263, 1 gene, copy number 5 (within-gene range 4–5): C5orf17.
- chr5:24,135,160–29,983,114, 59 genes, copy number 5: AC114930.1, AC010342.1, AC010387.1, Metazoa_SRP, CDH10, AC091885.2, AC091885.1, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228, LINC02211, AC099499.2, AC099499.1, AC106754.1, AC106754.2, AC022140.1, AC022140.2, RNU6-374P, AC022418.1, MSNP1, RNU4-43P, AC025475.1, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1, AC093300.1, LINC02103, AC008825.1, AC109472.1, RNU6-909P, AC008825.2, LINC02109, AC010385.2, LSP1P3, AC010385.1, AC010385.3, SUCLG2P4, AC024589.2, AC024589.1, AC024589.3, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1.
- chr5:38,845,858–40,835,222, 22 genes, copy number 5: OSMR, RICTOR, AIG1P1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72.
- chr7:37,032–149,527, 4 genes, copy number 5: AC215522.1, AC093627.1, AC093627.6, AC093627.5.
- chr7:2,679,522–2,844,308, 3 genes, copy number 5: AMZ1, GNA12, AC006028.1.
- chr12:25,959,029–28,581,511, 59 genes, copy number 5 (within-gene range 4–5): RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2, INTS13, FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L, ARNTL2, ARNTL2-AS1, SMCO2, RARS1P1, PPFIBP1, AC087257.1, AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2, MRPS35, Y_RNA, MANSC4, AC009511.2, KLHL42, AC009511.1, RN7SKP15, AC009511.3, AC008011.1, PTHLH, AC008011.2, CCDC91, AC022364.1, AC022364.2, AC022079.2, AC022079.1, RNU4-54P, RNA5SP355, AC084754.1.
- chr16:975,761–981,596, 1 gene, copy number 5 (within-gene range 2–5): CEROX1.
- chr20:62,872,250–62,937,952, 3 genes, copy number 5: ARF4P2, DIDO1, AL117379.1.
- chr21:43,092,956–43,168,646, 2 genes, copy number 7–9 (within-gene range 3–9): U2AF1, AP001631.2.
- chr21:43,159,066–43,162,277, 1 gene, copy number 9: AP001631.1.
- chr21:43,414,483–43,427,131, 1 gene, copy number 7: SIK1.
- chr21:44,172,169–44,207,399, 3 genes, copy number 5: AP001056.2, AP001056.1, AP001057.1.

Autosomal genes at a single copy (total copy number 1): 10,547. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
